Somatic mutation profile of tumor specimen TCGA-BT-A2LB-01A (aliquot TCGA-BT-A2LB-01A-11D-A18F-08) from TCGA case TCGA-BT-A2LB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 73.5 years (26,846 days).
Specimen TCGA-BT-A2LB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b921d23e-ebdb-4ceb-9219-83380680a9c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A2LB-10A (Blood Derived Normal), aliquot TCGA-BT-A2LB-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c7bdd9f-9a2d-4cf9-ba60-9d8401209e99

The open-access MAF lists 707 somatic variants for this specimen: 485 protein-altering or splice-affecting, 202 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 405, Silent 202, Nonsense Mutation 37, Frame Shift Del 16, Splice Site 11, 5'UTR 7, Splice Region 6, Intron 5, RNA 5, Frame Shift Ins 3, In Frame Del 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID2 | c.5260C>T p.R1754* | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as rs1565642121, COSV57607374; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KDM6A | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 30/57 reads (53%) | hotspot (GDC flag); catalogued as COSV65037942; called by muse, mutect2, varscan2
- NF1 | c.7591C>T p.Q2531* (on ENST00000358273 / NM_001042492.3; = p.Q2510* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as rs1555536372, CM1211100, COSV62210559, COSV62228825; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAD51C | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 25/72 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV61676742; called by muse, mutect2, varscan2
- TP53 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780071, CM120848, COSV52677226, COSV52796536, COSV53623808; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as COSV60916081; called by muse, mutect2, varscan2
- ABCC5 | c.3348G>A p.M1116I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV55593518; called by muse, mutect2, varscan2
- ABI1 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61018684; called by muse, mutect2, varscan2
- ABLIM2 | c.1213G>A p.D405N (on ENST00000341937 / NM_001130084.2; = p.D438N on NM_001130083.2) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.821); catalogued as COSV56407922, COSV99590383; called by muse, mutect2, varscan2
- ACBD3 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.515); catalogued as COSV64730782; called by muse, mutect2, varscan2
- ACKR4 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV51442901; called by muse, mutect2, varscan2
- ACP3 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV60485450; called by muse, mutect2, varscan2
- ADAM9 | c.1637A>G p.K546R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); catalogued as COSV65961280; called by muse, mutect2, varscan2
- ADM | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53403478; called by muse, mutect2, varscan2
- AFG3L2 | c.2132G>C p.R711T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV52312988, COSV52316117; called by muse, mutect2, varscan2
- AGT | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV64184771, COSV64185111; called by muse, mutect2, varscan2
- AHDC1 | c.4360C>T p.P1454S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.023); catalogued as COSV55940686; called by muse, mutect2, varscan2
- AJUBA | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs375437444, COSV52986033; called by muse, mutect2, varscan2
- AKAP13 | c.637C>T p.H213Y | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV63464627; called by muse, mutect2, varscan2
- AMELX | c.335T>C p.I112T | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61631827; called by muse, mutect2, varscan2
- AMY2B | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 55/195 reads (28%) | catalogued as COSV100796284; called by muse, mutect2, varscan2
- ANGPT4 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.863); catalogued as COSV67922297; called by muse, mutect2, varscan2
- ANP32A | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51189751; called by muse, mutect2, varscan2
- ANXA13 | c.451del p.I151Sfs*20 | Frame Shift Del (DEL) | VAF 20/158 reads (13%) | catalogued as rs759218332; called by mutect2, varscan2
- AP3B2 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as COSV55611961; called by muse, mutect2, varscan2
- APC | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 41/76 reads (54%) | catalogued as COSV57348738, COSV57363838, COSV57384634; called by muse, mutect2, varscan2
- ARHGAP17 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51509852; called by muse, mutect2, varscan2
- ARHGAP6 | c.1211A>G p.N404S | Missense Mutation (SNP) | VAF 117/209 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57299434; called by muse, mutect2, varscan2
- ARHGEF16 | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1416543157, COSV65682587; called by muse, mutect2, varscan2
- ARID3C | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as rs1393535263, COSV52408169; called by muse, mutect2, varscan2
- ARID4A | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV62165237; called by muse, mutect2, varscan2
- ARID4B | c.3595G>A p.D1199N | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV51607529; called by muse, varscan2
- ARID4B | c.3498G>C p.K1166N | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV51607543; called by muse, varscan2
- ASPM | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs775591782, COSV54133953; called by muse, mutect2, varscan2
- ASPSCR1 | c.662C>T p.S221L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs766418016, COSV60729996; called by muse, mutect2, varscan2
- ATP10B | c.3009G>C p.L1003F | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100515943, COSV59158930; called by muse, mutect2, varscan2
- ATP9A | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1235962124, COSV58764702; called by muse, mutect2, varscan2
- BAZ2B | c.2884C>T p.Q962* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99680963; called by muse, mutect2
- BIN1 | c.85-1G>A p.X29_splice | Splice Site (SNP) | VAF 54/139 reads (39%) | catalogued as COSV52120252; called by muse, mutect2, varscan2
- BMPR1B | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV52779671, COSV52780544; called by muse, mutect2, varscan2
- BMPR2 | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65811667; called by muse, mutect2, varscan2
- BNIP5 | c.1671C>T p.I557= | Splice Region (SNP) | VAF 22/61 reads (36%) | catalogued as COSV71325719; called by muse, mutect2, varscan2
- BOC | c.2825C>T p.S942L | Missense Mutation (SNP) | VAF 44/83 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as rs755406839, COSV56349055; called by muse, mutect2, varscan2
- BRD7 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV67159450; called by muse, mutect2, varscan2
- C11orf53 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54722194; called by muse, mutect2, varscan2
- C6orf47 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV63263961; called by muse, mutect2, varscan2
- C8B | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV100980766, COSV64778587; called by muse, mutect2, varscan2
- CACNA2D4 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs1008746452, COSV54954956; called by muse, mutect2, varscan2
- CAD | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.138); catalogued as COSV53029353; called by muse, mutect2, varscan2
- CAD | c.2257A>G p.T753A | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.036); catalogued as COSV53029364; called by muse, mutect2, varscan2
- CAPG | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.262); catalogued as COSV55708150; called by muse, mutect2, varscan2
- CARD10 | c.2805C>G p.N935K | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as rs773684555, COSV52658514; called by muse, mutect2, varscan2
- CASKIN1 | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58874763; called by muse, mutect2, varscan2
- CASKIN2 | c.2209G>C p.E737Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV58598168; called by muse, mutect2, varscan2
- CATIP | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs1160459818, COSV56823576; called by muse, mutect2, varscan2
- CD101 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV56718456; called by muse, mutect2, varscan2
- CD36 | c.1019A>G p.Y340C | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs764076950, COSV59216223; called by muse, mutect2, varscan2
- CENPT | c.433C>G p.P145A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV54651018; called by muse, mutect2, varscan2
- CFAP161 | c.854C>G p.P285R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs371058800, COSV54429845; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.370T>C p.S124P | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV51592785; called by muse, mutect2, varscan2
- CHD1 | c.4428-2A>G p.X1476_splice | Splice Site (SNP) | VAF 7/41 reads (17%) | catalogued as COSV52342690; called by muse, mutect2, varscan2
- CHD1 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV52342627; called by muse, mutect2, varscan2
- CHD1 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 60/195 reads (31%) | catalogued as COSV99399411, COSV99399989; called by muse, mutect2, varscan2
- CHD7 | c.1849A>G p.K617E | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.034); catalogued as COSV101418236; called by muse, mutect2, varscan2
- CHPF | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV60535913; called by muse, mutect2, varscan2
- CHPT1 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57534041; called by muse, mutect2, varscan2
- CHRD | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.121); catalogued as rs527889467, COSV52608149; called by muse, mutect2, varscan2
- CLASP2 | c.2599C>T p.P867S | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV56288295; called by muse, mutect2, varscan2
- CLPTM1 | c.428A>G p.D143G | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61612476; called by muse, mutect2
- CLPTM1 | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61612481; called by muse, mutect2
- CMTM8 | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56776532; called by muse, varscan2
- CNFN | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs751165575, COSV55771656; called by muse, mutect2, varscan2
- CNGB1 | c.3649G>A p.E1217K | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1056514077, COSV51903816; called by muse, mutect2, varscan2
- CNTN1 | c.801A>T p.G267= | Splice Region (SNP) | VAF 25/98 reads (26%) | catalogued as COSV61642564; called by muse, mutect2, varscan2
- CNTN3 | c.2087A>G p.E696G | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as rs779154110, COSV55178473; called by muse, varscan2
- CNTN3 | c.2057C>A p.P686Q | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55178481, COSV99723368; called by muse, varscan2
- COBLL1 | c.409A>G p.T137A (on ENST00000392717; = p.T99A on NM_014900.5) | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146685683; called by muse, mutect2, varscan2
- COL17A1 | c.2546A>G p.H849R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1324278419, COSV62228158; called by muse, mutect2, varscan2
- COL4A3 | c.1796G>C p.G599A | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67417547; called by muse, mutect2, varscan2
- COL6A3 | c.4631_4632del p.L1544Rfs*45 | Frame Shift Del (DEL) | VAF 21/137 reads (15%) | catalogued as COSV55098990; called by mutect2, pindel, varscan2
- COPS2 | c.62C>G p.S21C | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV54646363; called by muse, mutect2, varscan2
- CORO1C | c.472T>G p.W158G | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54597686; called by muse, mutect2, varscan2
- CPB2 | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 47/110 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.041); catalogued as COSV51676042; called by muse, mutect2, varscan2
- CR1L | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.574); catalogued as rs1245667818, COSV54325556, COSV54328937; called by muse, mutect2, varscan2
- CRBN | c.1145C>G p.P382R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146272907; called by muse, mutect2, varscan2
- CSRNP3 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as rs746285154, COSV58782351; called by muse, mutect2, varscan2
- CST4 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.026); catalogued as rs745520115, COSV54149437; called by muse, mutect2, varscan2
- CTCF | c.1051T>C p.F351L | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV50487321; called by muse, mutect2, varscan2
- CYP3A4 | c.1412G>A p.R471K (on ENST00000336411; = p.R440K on NM_017460.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV60503224; called by muse, mutect2, varscan2
- CYP3A4 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV60503235; called by muse, mutect2, varscan2
- DAGLA | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs1359845774, COSV57198055; called by muse, mutect2, varscan2
- DCAF1 | c.1810A>C p.I604L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV60044942; called by muse, mutect2, varscan2
- DCHS2 | n.233+1G>A | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as COSV59733091; called by muse, mutect2, varscan2
- DDIAS | c.1405A>T p.T469S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV61272731; called by muse, mutect2, varscan2
- DDX60L | c.4551G>A p.M1517I | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV52717658; called by muse, mutect2, varscan2
- DENND3 | c.1235C>G p.S412C | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.933); catalogued as COSV52804509; called by muse, mutect2, varscan2
- DENND5B | c.2007T>G p.S669R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV60905504; called by muse, mutect2, varscan2
- DHRS11 | c.635A>G p.K212R | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs776969648; called by muse, mutect2, varscan2
- DHRS4L2 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as rs551390746, COSV58730415; called by muse, mutect2, varscan2
- DHX30 | c.697G>A p.D233N (on ENST00000445061 / NM_138615.3; = p.D194N on NM_014966.3) | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV62394457; called by muse, mutect2, varscan2
- DISP2 | c.2068C>T p.L690F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.996); catalogued as rs1236631496, COSV99139968; called by mutect2, varscan2
- DLEC1 | c.3899A>G p.E1300G | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV57303068; called by muse, mutect2, varscan2
- DLL1 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV64538048; called by muse, mutect2, varscan2
- DMRT2 | c.1636G>C p.E546Q | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52402669; called by muse, mutect2, varscan2
- DMXL2 | c.3701G>C p.R1234T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51850887, COSV51852434; called by muse, mutect2, varscan2
- DMXL2 | c.2960C>T p.S987L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV51845760; called by muse, mutect2, varscan2
- DNAH11 | c.2785T>A p.F929I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as rs532612017, COSV60967222; called by mutect2, varscan2
- DNAH17 | c.12167A>G p.N4056S | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV67758475; called by muse, mutect2, varscan2
- DNTT | c.463T>C p.C155R | Missense Mutation (SNP) | VAF 35/167 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64523363; called by muse, mutect2, varscan2
- DOCK4 | c.1309A>G p.T437A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV70323719; called by muse, mutect2
- DPP3 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.278); catalogued as rs1462509737, COSV64757375; called by muse, mutect2, varscan2
- DTNB | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.794); catalogued as rs1285647225, COSV56480792; called by muse, mutect2, varscan2
- DUSP16 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV53808764; called by muse, mutect2, varscan2
- DUSP8 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs777772515, COSV59030743; called by muse, mutect2, varscan2
- E2F8 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV51464903; called by mutect2, varscan2
- EEFSEC | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV54629121; called by muse, mutect2, varscan2
- EFCAB5 | c.2416_2431del p.R806Efs*23 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as COSV57933424; called by mutect2, pindel, varscan2
- EIF3A | c.2992C>T p.P998S | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs369661440; called by muse, mutect2, varscan2
- EIF3B | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV62804105; called by muse, mutect2, varscan2
- EP300 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV54326876; called by muse, mutect2, varscan2
- EPHA2 | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV64454015; called by muse, mutect2, varscan2
- ESF1 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs572143127, COSV52522047; called by muse, mutect2, varscan2
- ETAA1 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV55474471; called by muse, varscan2
- EXOC4 | c.2105G>T p.R702L | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV54109967, COSV99552796; called by muse, mutect2, varscan2
- EXOC6 | c.2027A>G p.D676G | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as COSV53328680; called by muse, mutect2, varscan2
- EXPH5 | c.3071G>C p.R1024T | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV56205287; called by muse, mutect2, varscan2
- F2R | c.917G>T p.S306I | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV59929590; called by muse, mutect2, varscan2
- FAM114A1 | c.854G>C p.R285T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV62673861; called by muse, mutect2, varscan2
- FAM161A | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as rs760408265, COSV56767342; called by muse, mutect2, varscan2
- FAM166A | c.733T>C p.F245L | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV61118093; called by muse, mutect2, varscan2
- FAM193A | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV61196539; called by muse, mutect2, varscan2
- FAM83D | c.517A>G p.I173V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.397); catalogued as COSV54158215; called by muse, mutect2, varscan2
- FANCI | c.3130A>C p.I1044L (on ENST00000310775 / NM_001376911.1; = p.I984L on NM_018193.3) | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV55530649; called by muse, mutect2, varscan2
- FAT1 | c.2353A>G p.T785A | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs763165843, COSV71675149; called by muse, mutect2, varscan2
- FBXO36 | c.94C>G p.Q32E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV52268541; called by muse, mutect2, varscan2
- FGB | c.365C>A p.P122Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.591); catalogued as COSV57419014; called by muse, mutect2, varscan2
- FNIP2 | c.176G>A p.G59D | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52442887; called by muse, mutect2, varscan2
- FOXA1 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.601); catalogued as COSV51647835; called by muse, mutect2, varscan2
- FOXO1 | c.1241T>C p.L414S | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV65427627; called by muse, mutect2, varscan2
- FREM2 | c.772G>A p.A258T | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.258); catalogued as COSV54844609; called by muse, mutect2, varscan2
- FSTL5 | c.591T>G p.I197M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV60211969; called by muse, mutect2, varscan2
- FUT11 | c.868A>T p.T290S | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59543490; called by muse, mutect2, varscan2
- FZD3 | c.1566G>C p.E522D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.055); catalogued as COSV53536752; called by muse, mutect2, varscan2
- GALM | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); catalogued as COSV55372863; called by muse, mutect2, varscan2
- GALNT5 | c.2528A>C p.Q843P | Missense Mutation (SNP) | VAF 132/417 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV52039430; called by muse, mutect2, varscan2
- GAR1 | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); catalogued as COSV56993156; called by muse, mutect2, varscan2
- GBP5 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs777397329, COSV58593645; called by muse, mutect2, varscan2
- GBP7 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54010757; called by muse, mutect2, varscan2
- GGTLC2 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs760624506, COSV67854457; called by muse, mutect2, varscan2
- GIGYF2 | c.3839C>T p.S1280L | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV65251676; called by muse, mutect2, varscan2
- GOLGA3 | c.4075A>C p.N1359H | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs779002581, COSV52637575; called by muse, mutect2, varscan2
- GOLGA5 | c.1777C>A p.Q593K | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV50834062; called by muse, mutect2, varscan2
- GOLGB1 | c.6985G>A p.E2329K | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as COSV61468289; called by muse, mutect2, varscan2
- GOLGB1 | c.4102G>A p.E1368K | Missense Mutation (SNP) | VAF 327/487 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.397); catalogued as rs762656767, COSV61465585; called by muse, mutect2, varscan2
- GPKOW | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 38/63 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV50243936; called by muse, mutect2, varscan2
- GPR151 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs147138565; called by muse, mutect2, varscan2
- GSDMD | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52797774, COSV52798409; called by muse, mutect2, varscan2
- GTF2F1 | c.1064G>A p.S355N | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV66726451; called by muse, mutect2, varscan2
- HAL | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV54119080; called by muse, mutect2, varscan2
- HIPK3 | c.1579A>G p.M527V | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as COSV57564103; called by muse, mutect2, varscan2
- HMBOX1 | c.439T>C p.Y147H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV55070296; called by muse, mutect2, varscan2
- HMCN1 | c.223A>G p.K75E | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.802); catalogued as COSV54900195; called by muse, mutect2, varscan2
- HOXC5 | c.524A>T p.H175L | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54537686; called by muse, mutect2, varscan2
- HRAS | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV54238391, COSV54244417; called by muse, mutect2, varscan2
- HSPA2 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV55970685; called by muse, mutect2, varscan2
- HTRA2 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV51210052; called by muse, mutect2, varscan2
- IDI2 | c.239A>G p.Y80C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.038); catalogued as COSV52988562; called by muse, mutect2, varscan2
- IFT140 | c.2536G>C p.E846Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV54153882; called by mutect2, varscan2
- IL17REL | c.866G>A p.R289H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.381); catalogued as rs755575606, COSV58008678; called by muse, mutect2, varscan2
- IL4R | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.469); catalogued as COSV50154863; called by muse, mutect2, varscan2
- ILDR2 | c.392A>C p.Q131P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as COSV54833359; called by muse, mutect2, varscan2
- INKA2 | c.37C>T p.R13C | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.313); catalogued as COSV100615750, COSV61878490; called by muse, mutect2, varscan2
- INO80 | c.2806G>A p.E936K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV62740357; called by muse, varscan2
- IQSEC2 | c.3033G>T p.Q1011H (on ENST00000642864 / NM_001111125.3; = p.Q806H on NM_015075.2) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as COSV64726971; called by muse, mutect2, varscan2
- ITGB5 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 153/204 reads (75%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as COSV56147872, COSV56151042; called by muse, mutect2, varscan2
- ITIH1 | c.138+1G>T p.X46_splice | Splice Site (SNP) | VAF 42/125 reads (34%) | catalogued as COSV56256831; called by muse, mutect2, varscan2
- IVNS1ABP | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.893); catalogued as COSV62250036; called by muse, mutect2, varscan2
- JAKMIP3 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs763063160, COSV53822383; called by muse, mutect2, varscan2
- KCNH8 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769502038, COSV60470269; called by muse, mutect2, varscan2
- KDM4A | c.3100G>A p.E1034K | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV53517089; called by muse, mutect2, varscan2
- KIFC1 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.108); catalogued as COSV65737733; called by muse, mutect2, varscan2
- KIFC2 | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1037024198; called by muse, mutect2, varscan2
- KIRREL1 | c.1778G>A p.R593Q | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); catalogued as rs562996454, COSV63289481; called by muse, mutect2
- KL | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV66309423; called by muse, mutect2, varscan2
- KRT33B | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751713129, COSV52440410; called by muse, mutect2, varscan2
- KRT84 | c.755A>G p.K252R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.95); catalogued as rs1353548692, COSV57772574, COSV99230914; called by muse, mutect2, varscan2
- LCLAT1 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58375537; called by muse, mutect2, varscan2
- LDB1 | c.1057G>A p.E353K (on ENST00000425280 / NM_001321612.2; = p.E319K on NM_003893.5) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV63289589, COSV63289595; called by muse, mutect2, varscan2
- LGR5 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 30/78 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV57007555; called by muse, mutect2, varscan2
- LIMA1 | c.1489C>T p.P497S | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV57966951; called by muse, mutect2, varscan2
- LRATD1 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs751639770, COSV54473612; called by muse, mutect2, varscan2
- LRFN5 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53267165; called by muse, mutect2, varscan2
- LRP2 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.907); catalogued as COSV55548360, COSV55560345, COSV55563763; called by muse, mutect2
- LRRK2 | c.6688G>A p.E2230K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs201317931, COSV54144922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LTB4R2 | c.586G>A p.D196N (on ENST00000528054; = p.D165N on NM_019839.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.125); catalogued as COSV51866906; called by muse, mutect2, varscan2
- LUC7L | c.997A>G p.R333G | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as COSV53459564; called by muse, mutect2, varscan2
- MAGEA11 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.946); catalogued as COSV60756774, COSV60757325; called by muse, mutect2, varscan2
- MAML1 | c.1832A>G p.Y611C | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52984657; called by muse, mutect2, varscan2
- MAN2B1 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV55472319; called by muse, mutect2, varscan2
- MASP2 | c.923A>C p.N308T | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV68897093; called by muse, mutect2, varscan2
- MCM3AP | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52442685; called by muse, mutect2, varscan2
- MCM8 | c.2065C>T p.L689F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54516452; called by muse, mutect2, varscan2
- MED11 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as rs767655018, COSV53411901; called by muse, mutect2, varscan2
- MEOX1 | c.672G>C p.M224I | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59355426, COSV59356745; called by muse, mutect2, varscan2
- METTL27 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320763602, COSV52896611; called by muse, mutect2, varscan2
- MID2 | c.610A>G p.N204D | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.336); catalogued as COSV53311819; called by muse, mutect2, varscan2
- MINDY1 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.836); catalogued as COSV56499912; called by muse, mutect2, varscan2
- MKNK1 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57862160; called by muse, mutect2, varscan2
- MORC1 | c.2540T>C p.L847S | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as COSV51725548; called by muse, mutect2, varscan2
- MORC4 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV55244830; called by muse, mutect2, varscan2
- MPHOSPH8 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV64055811; called by muse, mutect2, varscan2
- MPHOSPH8 | c.605G>C p.R202T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV64056592; called by muse, mutect2, varscan2
- MPHOSPH8 | c.980G>C p.R327T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.205); catalogued as COSV64055230, COSV64056604; called by muse, mutect2, varscan2
- MPP5 | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55531057; called by muse, mutect2, varscan2
- MRGPRE | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV67745832; called by muse, mutect2, varscan2
- MTERF2 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53528053; called by muse, mutect2, varscan2
- MTUS1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV50570019; called by muse, mutect2, varscan2
- MUC16 | c.30148G>A p.V10050M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.865); catalogued as COSV67479797; called by muse, mutect2, varscan2
- MUC17 | c.9446C>T p.S3149F | Missense Mutation (SNP) | VAF 72/402 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV60296158, COSV60306999; called by muse, mutect2, varscan2
- MYBPC1 | c.716A>G p.K239R (on ENST00000550270 / NM_206820.2; = p.K264R on NM_002465.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV62255427; called by mutect2, varscan2
- MYCBP2 | c.9843C>T p.V3281= (on ENST00000357337; = p.V3319= on NM_015057.5) | Splice Region (SNP) | VAF 27/63 reads (43%) | catalogued as COSV62029624; called by muse, mutect2, varscan2
- MYO18A | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62870259; called by muse, mutect2, varscan2
- MYOF | c.3479C>T p.S1160L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63707603; called by muse, mutect2, varscan2
- N4BP2 | c.637A>C p.N213H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as COSV54704572; called by muse, mutect2, varscan2
- NAIP | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 24/114 reads (21%) | catalogued as COSV52002856, COSV99519279; called by muse, mutect2, varscan2
- NCK1 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56638695; called by muse, mutect2, varscan2
- NCKAP5 | c.5512G>C p.A1838P | Missense Mutation (SNP) | VAF 45/262 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV58460684; called by muse, mutect2, varscan2
- NCOA1 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.22); catalogued as COSV56049108; called by muse, mutect2, varscan2
- NEUROD6 | c.99G>T p.K33N | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV51772503, COSV99773983; called by muse, mutect2, varscan2
- NFKB1 | c.2645C>T p.T882I (on ENST00000394820 / NM_001382627.1; = p.T883I on NM_003998.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as rs1462393245; called by muse, mutect2, varscan2
- NFS1 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs766798320, COSV60764329, COSV60764521; called by muse, mutect2, varscan2
- NHLH2 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV57202566; called by muse, mutect2, varscan2
- NIP7 | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); catalogued as COSV54742957; called by muse, mutect2, varscan2
- NKX2-8 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs753841581, COSV51874244, COSV99352366; called by muse, mutect2, varscan2
- NOP2 | c.187A>G p.K63E | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV58906160; called by muse, mutect2, varscan2
- NPC1 | c.288-1G>A p.X96_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV52581158; called by muse, mutect2, varscan2
- NPEPPS | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.03); catalogued as COSV59104054; called by muse, mutect2, varscan2
- NPY1R | c.1027C>G p.R343G | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.251); catalogued as COSV56713995, COSV56714699, COSV56715449; called by muse, mutect2, varscan2
- NRG1 | c.341T>C p.V114A | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as COSV55168274; called by muse, mutect2, varscan2
- NRL | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs1395326246, COSV53745392; called by muse, mutect2, varscan2
- NUCB1 | c.969G>T p.R323S | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as COSV54387294; called by muse, mutect2, varscan2
- NUP133 | c.3175G>A p.D1059N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1395123898, COSV54573501; called by muse, mutect2, varscan2
- OAS2 | c.1265C>A p.T422N | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.265); catalogued as rs1404382334, COSV60803467; called by muse, mutect2, varscan2
- OBSCN | c.7699G>A p.A2567T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs1458756940, COSV52800349; called by muse, mutect2, varscan2
- OPA1 | c.2147C>T p.T716I (on ENST00000361510 / NM_130837.3; = p.T661I on NM_015560.3) | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV62482062; called by muse, mutect2, varscan2
- OR10K1 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 48/192 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV56870411; called by muse, mutect2, varscan2
- OR1B1 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | catalogued as rs920627231; called by muse, mutect2, varscan2
- OR2AE1 | c.712G>C p.A238P | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60390637; called by muse, mutect2, varscan2
- OR2M3 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 62/181 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV71759184, COSV71759200; called by muse, mutect2, varscan2
- OR4C15 | c.862A>G p.K288E (on ENST00000314644; = p.K234E on NM_001001920.2) | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); catalogued as rs774444921, COSV58954281; called by muse, mutect2, varscan2
- OR6C65 | c.661A>G p.K221E | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as COSV65569078; called by muse, mutect2, varscan2
- OTOF | c.328-1G>C p.X110_splice | Splice Site (SNP) | VAF 10/97 reads (10%) | catalogued as COSV55510528; called by muse, mutect2, varscan2
- OTOGL | c.428G>A p.G143E (on ENST00000547103; = p.G134E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72007015; called by muse, mutect2, varscan2
- OTUD5 | c.1671G>A p.M557I | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV50237626; called by muse, mutect2, varscan2
- OTX1 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV56995491, COSV56996208; called by muse, mutect2, varscan2
- PC | c.3026C>T p.S1009L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199771464, COSV58992778, COSV58993342, COSV58993758; called by muse, varscan2
- PCDHGB1 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53989636, COSV53992249; called by muse, mutect2, varscan2
- PDCD4 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV54524009; called by muse, mutect2, varscan2
- PDCD5 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV55678719; called by muse, mutect2, varscan2
- PDE12 | c.1352G>A p.C451Y | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV60819031; called by muse, mutect2, varscan2
- PDE3A | c.2261G>A p.R754K | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV62977878; called by muse, mutect2, varscan2
- PDX1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.222); catalogued as COSV66847313; called by muse, mutect2, varscan2
- PEAK1 | c.4795A>C p.I1599L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56939647; called by muse, mutect2, varscan2
- PFKFB1 | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 28/45 reads (62%) | PolyPhen benign (0); catalogued as rs1288738705, COSV51504773; called by muse, mutect2, varscan2
- PGGHG | c.2069C>T p.P690L | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV66888373; called by muse, mutect2, varscan2
- PIK3R4 | c.3474T>C p.I1158= | Splice Region (SNP) | VAF 28/56 reads (50%) | catalogued as COSV63242496; called by muse, mutect2, varscan2
- PLXNA1 | c.3076A>G p.I1026V | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.042); catalogued as COSV52529879; called by muse, mutect2
- PLXNA4 | c.4142G>A p.R1381H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs368621356; called by muse, mutect2, varscan2
- POLG2 | c.23G>A p.R8K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV56750331; called by muse, mutect2, varscan2
- POT1 | c.1585G>A p.V529M | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs34973253; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEA | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.043); catalogued as rs368067417; called by muse, mutect2, varscan2
- PPP1R10 | c.2765G>A p.R922H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs377763869; called by muse, mutect2, varscan2
- PPP1R16B | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV55380717; called by muse, mutect2, varscan2
- PPP3CA | c.1396A>G p.K466E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV59927477; called by muse, mutect2, varscan2
- PRB2 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 30/121 reads (25%) | catalogued as COSV101231411, COSV66982539; called by muse, varscan2
- PRB2 | c.9G>C p.L3F | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.081); catalogued as COSV101231412, COSV66984507; called by muse, varscan2
- PRDX5 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV50006981, COSV99134659; called by muse, mutect2, varscan2
- PREB | c.895G>A p.G299S | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53207235; called by muse, mutect2, varscan2
- PRG2 | c.290A>C p.K97T | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV61293863; called by muse, mutect2, varscan2
- PRKAA2 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV64805138; called by muse, mutect2, varscan2
- PRPF4 | c.934G>A p.D312N (on ENST00000374198 / NM_001322267.2; = p.D313N on NM_004697.5) | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as COSV65253114; called by muse, mutect2, varscan2
- PRRT2 | c.614C>T p.S205L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV54885170; called by muse, mutect2, varscan2
- PSIP1 | c.1118G>T p.C373F | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66255205; called by muse, mutect2, varscan2
- PTPRT | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.048); catalogued as rs773011187, COSV61999941; called by muse, mutect2, varscan2
- PUM2 | c.2642A>C p.H881P | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57583599; called by muse, mutect2, varscan2
- QRICH2 | c.1318G>T p.D440Y | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV53155475; called by muse, mutect2, varscan2
- RAB11FIP2 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.147); catalogued as COSV62925724; called by muse, mutect2, varscan2
- RAD51AP2 | c.1849T>C p.Y617H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV67588586; called by muse, mutect2, varscan2
- RAD51C | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV53620946; called by muse, mutect2, varscan2
- RAD52 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV57273550; called by muse, mutect2, varscan2
- RALGAPA2 | c.4717G>A p.E1573K | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV52504084; called by muse, mutect2
- RARA | c.896A>G p.N299S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as COSV54190076; called by muse, mutect2, varscan2
- RASAL3 | c.2965C>T p.P989S | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV54609985; called by muse, mutect2, varscan2
- RASSF2 | c.78T>A p.H26Q | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV65082628; called by muse, mutect2, varscan2
- RBM12B | c.1500G>C p.Q500H | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV67898501; called by muse, mutect2, varscan2
- RBM27 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV54592149; called by muse, mutect2, varscan2
- RBM45 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV53721789; called by muse, mutect2, varscan2
- RBM5 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.143); catalogued as COSV61738359; called by muse, mutect2, varscan2
- RBM6 | c.1424C>T p.A475V | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1452807934, COSV56485527; called by muse, mutect2, varscan2
- RDH10 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53583462; called by muse, mutect2, varscan2
- RGS14 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.964); catalogued as rs1204441848, COSV68771297; called by muse, mutect2, varscan2
- RHOBTB1 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV61959389; called by muse, mutect2, varscan2
- RHOV | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55027836; called by muse, mutect2, varscan2
- RHOV | c.212A>T p.Q71L | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.018); catalogued as COSV55027848; called by muse, mutect2, varscan2
- RICTOR | c.1511C>G p.T504R | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.014); catalogued as COSV57126411; called by muse, mutect2, varscan2
- RNF216 | c.1366C>T p.L456F (on ENST00000425013 / NM_207116.3; = p.L513F on NM_207111.4) | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs201663977, COSV66291728; called by muse, mutect2, varscan2
- ROS1 | c.3151A>G p.I1051V | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63858538; called by muse, mutect2, varscan2
- RPL4 | c.1003A>G p.M335V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV57181617; called by muse, mutect2, varscan2
- RPS6KC1 | c.2765G>A p.R922K | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.706); catalogued as COSV65301283; called by muse, mutect2, varscan2
- SAMD13 | c.160A>G p.M54V (on ENST00000370671; = p.M48V on NM_001010971.3) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs754177834, COSV65745219; called by muse, mutect2, varscan2
- SAMD3 | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV62387454; called by mutect2, varscan2
- SASH3 | c.272T>C p.M91T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs775165842, COSV63556254; called by muse, mutect2, varscan2
- SCN1A | c.1712G>A p.R571K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV57662076, COSV57672659; called by muse, mutect2, varscan2
- SDCBP2 | c.737A>G p.K246R (on ENST00000339987 / NM_001199784.1; = p.K161R on NM_015685.5) | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as COSV60590165; called by muse, mutect2, varscan2
- SEC23IP | c.53C>T p.S18L | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1442393779, COSV64832290; called by muse, mutect2, varscan2
- SEC23IP | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV64832294; called by muse, mutect2, varscan2
- SEC31B | c.2057A>G p.Y686C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64845126; called by muse, mutect2, varscan2
- SEMA3A | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.59); catalogued as COSV54879695; called by muse, mutect2, varscan2
- SEMA3D | c.1503+2T>C p.X501_splice | Splice Site (SNP) | VAF 6/35 reads (17%) | catalogued as COSV52389723; called by muse, mutect2, varscan2
- SERAC1 | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65597341; called by muse, mutect2, varscan2
- SERINC3 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.093); catalogued as COSV54856819; called by muse, mutect2, varscan2
- SERPINE2 | c.664C>A p.Q222K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV51458946; called by muse, mutect2, varscan2
- SETDB2 | c.686A>T p.Q229L | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.255); catalogued as COSV51645667; called by muse, mutect2, varscan2
- SF3B4 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54966226; called by muse, mutect2, varscan2
- SHOC2 | c.1675C>G p.Q559E | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54623236; called by muse, mutect2, varscan2
- SHQ1 | c.1349C>T p.S450F | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.17); catalogued as rs748702725, COSV57763921; called by muse, mutect2
- SHQ1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 80/231 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); catalogued as COSV57765661, COSV57766849; called by muse, mutect2, varscan2
- SLC11A2 | c.1583T>C p.V528A (on ENST00000394904 / NM_001379455.1; = p.V499A on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.274); catalogued as COSV50372718; called by muse, mutect2, varscan2
- SLC25A46 | c.593A>G p.Q198R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63506930; called by muse, mutect2, varscan2
- SLC25A6 | c.821C>A p.A274E | Missense Mutation (SNP) | VAF 166/250 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58431511, COSV58432534; called by muse, mutect2, varscan2
- SLC29A4 | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV51873644; called by muse, mutect2, varscan2
- SLC2A2 | c.451C>G p.H151D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.786); catalogued as COSV58587437; called by muse, mutect2, varscan2
- SLC2A4 | c.473T>C p.M158T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs572587255, COSV50301623; called by muse, mutect2, varscan2
- SLC45A3 | c.159G>A p.M53I | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV65655203; called by muse, mutect2, varscan2
- SLC52A2 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57352666; called by muse, mutect2, varscan2
- SLC8A3 | c.2420G>C p.S807T (on ENST00000381269 / NM_183002.3; = p.S805T on NM_033262.4) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53691245, COSV53691301; called by muse, mutect2, varscan2
- SLIT3 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1230535907, COSV60622505; called by muse, mutect2, varscan2
- SMCHD1 | c.4070T>C p.I1357T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV55263087; called by muse, mutect2, varscan2
- SMYD1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.247); catalogued as COSV70225573; called by muse, mutect2, varscan2
- SNF8 | c.352C>T p.L118= | Splice Region (SNP) | VAF 4/29 reads (14%) | catalogued as rs1489681400; called by muse, varscan2
- SNTG2 | c.380T>C p.I127T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as COSV57995985; called by muse, mutect2, varscan2
- SNX11 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV63658930; called by muse, mutect2, varscan2
- SP110 | c.1956+1G>A p.X652_splice | Splice Site (SNP) | VAF 11/36 reads (31%) | catalogued as COSV51261570; called by muse, mutect2, varscan2
- SP140L | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV54746090; called by muse, mutect2, varscan2
- SPEN | c.10906G>A p.E3636K | Missense Mutation (SNP) | VAF 80/246 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV65270817; called by muse, varscan2
- SPOCK3 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 21/59 reads (36%) | catalogued as COSV62717823; called by muse, mutect2, varscan2
- STEAP2 | c.680dup p.L228Pfs*14 | Frame Shift Ins (INS) | VAF 28/57 reads (49%) | catalogued as rs754344704; called by mutect2, varscan2
- STK36 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV55308555; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs565482782; called by muse, mutect2, varscan2
- STRN3 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV62580903; called by muse, mutect2, varscan2
- SUPT20H | c.961G>A p.D321N (on ENST00000350612 / NM_001014286.3; = p.D322N on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV62248710, COSV62248840; called by muse, mutect2, varscan2
- SYT1 | c.543C>G p.Y181* | Nonsense Mutation (SNP) | VAF 34/77 reads (44%) | catalogued as COSV54034588, COSV54044449; called by muse, mutect2, varscan2
- SYT7 | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.431); catalogued as rs767878306, COSV55657646; called by muse, mutect2, varscan2
- SZT2 | c.8660G>A p.R2887Q (on ENST00000634258 / NM_001365999.1; = p.R2830Q on NM_015284.4) | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.797); catalogued as rs141085666; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SZT2 | c.9547G>A p.E3183K (on ENST00000634258 / NM_001365999.1; = p.E3126K on NM_015284.4) | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs772006871, COSV65094205, COSV65095047; called by muse, mutect2, varscan2
- TAP1 | c.1966C>T p.Q656* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100841101; called by muse, mutect2, varscan2
- TC2N | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756200562; called by muse, mutect2, varscan2
- TCF20 | c.3542C>T p.S1181F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV59494222; called by muse, mutect2, varscan2
- TDRD5 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs563073215, COSV54246757; called by muse, mutect2, varscan2
- TENM3 | c.386A>G p.E129G | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV69314024; called by muse, mutect2, varscan2
- TEP1 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.046); catalogued as COSV52996211, COSV53002699; called by muse, mutect2, varscan2
- TERF2 | c.331C>G p.R111G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54748236; called by muse, mutect2, varscan2
- THAP10 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51436848; called by muse, mutect2, varscan2
- TIAM2 | c.3310A>G p.I1104V | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV51642681; called by muse, mutect2, varscan2
- TKFC | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); catalogued as rs770693680, COSV53652872; called by muse, mutect2
- TMED4 | c.534+1G>A p.X178_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as COSV56942214; called by muse, mutect2, varscan2
- TMEM159 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV51786209, COSV99238871; called by muse, mutect2, varscan2
- TMEM182 | c.308C>G p.S103W | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV68425238; called by muse, mutect2, varscan2
- TMEM19 | c.120C>A p.S40R | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV57000626; called by muse, mutect2, varscan2
- TMPO | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); catalogued as COSV54124317; called by muse, mutect2, varscan2
- TMPRSS7 | c.1888T>C p.Y630H (on ENST00000452346; = p.Y504H on NM_001042575.2) | Missense Mutation (SNP) | VAF 69/625 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.028); catalogued as COSV69981713; called by muse, mutect2, varscan2
- TNFRSF10C | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.071); catalogued as rs1227773384, COSV63512056; called by muse, mutect2, varscan2
- TNKS2 | c.2234C>G p.A745G | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV65416168; called by muse, mutect2, varscan2
- TNPO2 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV63509242; called by muse, mutect2, varscan2
- TNS1 | c.126G>C p.E42D | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as rs1464950790, COSV50729407; called by muse, mutect2, varscan2
- TOPBP1 | c.3215A>C p.Q1072P | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53439084; called by muse, mutect2, varscan2
- TRAPPC8 | c.3861G>C p.L1287F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV51974742; called by muse, mutect2, varscan2
- TRIM37 | c.118A>G p.I40V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV51881847, COSV51886501; called by muse, mutect2, varscan2
- TRIM60 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs377134665; called by muse, mutect2, varscan2
- TRMT11 | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.813); catalogued as COSV57673553; called by muse, mutect2, varscan2
- TRMT12 | c.814G>T p.V272F | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.222); catalogued as COSV60777516; called by muse, mutect2, varscan2
- TRMT13 | c.8C>G p.T3S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV54929078, COSV99790973; called by muse, mutect2, varscan2
- TRMT61A | c.9C>G p.F3L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV54569373; called by muse, mutect2, varscan2
- TROAP | c.509C>G p.S170C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57745129; called by muse, mutect2, varscan2
- TRPM1 | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV56638243; called by muse, mutect2, varscan2
- TRPS1 | c.2010A>T p.K670N (on ENST00000220888 / NM_001330599.2; = p.K683N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV55251867; called by muse, mutect2, varscan2
- TSEN54 | c.500T>C p.V167A | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV58691977; called by muse, mutect2, varscan2
- TSKS | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769280647, COSV55874069; called by muse, mutect2, varscan2
- TSPAN6 | c.575T>A p.V192E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV65957461; called by muse, mutect2, varscan2
- TTC13 | c.2144C>T p.T715I | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as COSV64169179; called by muse, mutect2, varscan2
- TTC13 | c.962A>C p.K321T | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.577); catalogued as COSV64169183; called by muse, mutect2, varscan2
- TTC21A | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57187448; called by muse, mutect2, varscan2
- TTC9 | c.488A>C p.N163T | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56448708; called by muse, mutect2, varscan2
- TTLL12 | c.1015T>G p.S339A | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV53356217; called by muse, mutect2, varscan2
- TTN | c.66493A>G p.R22165G (on ENST00000591111; = p.R14741G on NM_003319.4) | Missense Mutation (SNP) | VAF 36/101 reads (36%) | PolyPhen possibly damaging (0.54); catalogued as COSV60199641; called by muse, mutect2, varscan2
- TTN | c.2272C>G p.H758D (on ENST00000591111; = p.H712D on NM_003319.4) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | PolyPhen benign (0.033); catalogued as COSV60199660; called by muse, mutect2, varscan2
- UBC | c.-1A>C | Splice Region (SNP) | VAF 46/126 reads (37%) | catalogued as COSV100298946; called by muse, mutect2, varscan2
- UBE3B | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV55095819, COSV99783877; called by muse, mutect2, varscan2
- UBE3B | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.29); catalogued as COSV55095845; called by muse, mutect2, varscan2
- UBE4B | c.2761A>G p.N921D (on ENST00000343090 / NM_001105562.3; = p.N792D on NM_006048.5) | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV53536872; called by muse, mutect2, varscan2
- UBP1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV52146627; called by muse, mutect2, varscan2
- UBQLN2 | c.940G>A p.D314N | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.233); catalogued as COSV57740120; called by muse, mutect2, varscan2
- UGT2A3 | c.1269A>C p.L423F | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV52361196; called by muse, mutect2, varscan2
- UGT2B17 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV100497222; called by muse, mutect2, varscan2
- ULK2 | c.1349G>C p.G450A | Missense Mutation (SNP) | VAF 81/174 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV64447055; called by muse, mutect2, varscan2
- ULK4 | c.1768del p.E590Kfs*20 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | catalogued as COSV57215461; called by pindel, varscan2
- USP47 | c.3443A>G p.K1148R (on ENST00000399455 / NM_001372095.1; = p.K1060R on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.931); catalogued as COSV59694370; called by muse, mutect2, varscan2
- USP8 | c.1859G>A p.R620K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV56166174; called by muse, mutect2, varscan2
- UTRN | c.7381G>A p.E2461K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV62341480; called by muse, mutect2, varscan2
- VARS2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 46/83 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV52560174; called by muse, mutect2, varscan2
- VPS26A | c.876A>G p.I292M | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV54968697; called by muse, mutect2, varscan2
- VSX1 | c.549C>A p.F183L | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV65021816; called by muse, mutect2, varscan2
- VWA8 | c.4715G>A p.G1572E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64998435; called by muse, mutect2, varscan2
- WDR44 | c.1664A>G p.N555S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as COSV54166107; called by muse, mutect2, varscan2
- WDR76 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748412917, COSV55478599; called by muse, mutect2, varscan2
- YARS2 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.714); catalogued as COSV61401965, COSV61402239; called by muse, mutect2, varscan2
- YES1 | c.1466A>G p.Y489C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58851425; called by muse, mutect2, varscan2
- ZBTB21 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60404989; called by muse, mutect2, varscan2
- ZBTB22 | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV56471340; called by muse, mutect2, varscan2
- ZFP37 | c.1186G>T p.V396L | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV65287838; called by muse, mutect2, varscan2
- ZMYM2 | c.2630C>T p.T877I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV67036062; called by muse, mutect2, varscan2
- ZNF226 | c.1043C>T p.S348L | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1361512795, COSV56197324; called by muse, mutect2, varscan2
- ZNF300 | c.1795C>T p.H599Y | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51041467; called by muse, mutect2, varscan2
- ZNF418 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 74/123 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68676152; called by muse, mutect2, varscan2
- ZNF521 | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 30/68 reads (44%) | catalogued as COSV99052429; called by muse, mutect2, varscan2
- ZNF595 | c.1657G>C p.E553Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.481); catalogued as COSV59546740, COSV59551873; called by muse, mutect2, varscan2
- ZNF606 | c.2246C>T p.S749F | Missense Mutation (SNP) | VAF 81/114 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV58705322, COSV58707130; called by muse, mutect2, varscan2
- ZNF839 | c.1364C>G p.P455R (on ENST00000558850 / NM_001267827.1; = p.P571R on NM_018335.5) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.481); catalogued as COSV51758458; called by muse, mutect2, varscan2
- ZRANB3 | c.3026G>A p.R1009K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV51508979; called by muse, mutect2, varscan2
- ZSWIM8 | c.3089C>T p.S1030F (on ENST00000605216 / NM_001242487.2; = p.S1035F on NM_015037.3) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67133579; called by muse, mutect2, varscan2
- ALPK3 | c.3914C>T p.S1305L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AMOTL1 | c.1378C>T p.Q460* | Nonsense Mutation (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- C14orf39 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | called by muse, mutect2, varscan2
- C21orf62 | c.527_529del p.N176del | In Frame Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- CCDC116 | c.85A>T p.K29* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | called by muse, mutect2, varscan2
- CCNY | c.732_734delinsT p.T245Gfs*13 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by pindel, varscan2*
- DSTYK | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.019); called by muse, mutect2
- FARP1 | c.1926G>A p.W642* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- FCGBP | c.10540T>C p.Y3514H | Missense Mutation (SNP) | VAF 45/65 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FMNL1 | c.1570G>C p.G524R | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIK1 | c.1570-1G>C p.X524_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2
- HLA-DQB1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.121); called by muse, mutect2
- ICE1 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.045); called by muse, mutect2
- IL1A | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- INSRR | c.1486del p.A496Qfs*57 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- KMT2A | c.4418del p.N1473Ifs*113 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- NFE2L3 | c.759_771del p.N254Lfs*38 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- NHLRC3 | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 22/73 reads (30%) | called by muse, mutect2, varscan2
- NOX5 | c.907C>T p.Q303* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- NPTXR | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- NTS | c.462_474del p.N155Dfs*30 | Frame Shift Del (DEL) | VAF 18/101 reads (18%) | called by mutect2, pindel, varscan2
- NUP133 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- NUP210L | c.3565-18_3594del p.X1189_splice | Splice Site (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel
- NUP98 | c.3054_3078del p.K1019Vfs*18 (on ENST00000359171 / NM_001365126.1; = p.K1002Vfs*18 on NM_016320.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | called by mutect2, pindel
- P4HA1 | c.643del p.V215Yfs*20 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- PADI1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2
- PCDH15 | c.4641_4678del p.A1548Ifs*3 | Frame Shift Del (DEL) | VAF 18/137 reads (13%) | called by mutect2, pindel
- PHF20L1 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); called by muse, mutect2
- PHYHIPL | c.454_465delinsT p.E152Ffs*19 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by pindel, varscan2*
- PLEKHG4 | c.2045_2065del p.L682_E688del | In Frame Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PLXNB2 | c.3946dup p.L1316Pfs*79 | Frame Shift Ins (INS) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- PSMD1 | c.739C>T p.Q247* | Nonsense Mutation (SNP) | VAF 51/170 reads (30%) | called by muse, mutect2, varscan2
- PTPN12 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2
- RIOX2 | c.74_79dup p.E25_A26dup | In Frame Ins (INS) | VAF 12/67 reads (18%) | called by mutect2, varscan2
- RLN2 | c.190C>T p.Q64* (on ENST00000381627 / NM_134441.3; = p.Q15* on NM_005059.3) | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2
- RMC1 | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 34/119 reads (29%) | called by muse, mutect2, varscan2
- RNF2 | c.50G>A p.W17* | Nonsense Mutation (SNP) | VAF 32/109 reads (29%) | called by muse, mutect2, varscan2
- RPL22L1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- RTCB | c.373_387del p.R125_T129del | In Frame Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel
- SFRP4 | c.969del p.K324Nfs*57 | Frame Shift Del (DEL) | VAF 43/161 reads (27%) | called by mutect2, pindel, varscan2
- SLC17A9 | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- SLC38A10 | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.1765C>T p.Q589* | Nonsense Mutation (SNP) | VAF 60/124 reads (48%) | called by muse, mutect2, varscan2
- SPEM2 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 60/138 reads (43%) | called by muse, mutect2, varscan2
- SYDE1 | c.1720del p.R574Afs*61 | Frame Shift Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- THRAP3 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- USP24 | c.5268G>A p.W1756* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | called by muse, varscan2
- USP9X | c.3810+1_3810+2dup | Frame Shift Ins (INS) | VAF 15/30 reads (50%) | called by mutect2, pindel, varscan2
- VPS8 | c.1810A>G p.K604E (on ENST00000625842 / NM_001349294.1; = p.K602E on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- WASHC2C | c.3880G>A p.D1294N (on ENST00000336378; = p.D1273N on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- WT1 | c.1508G>C p.*503Sext*22 | Nonstop Mutation (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- WWP1 | c.1366G>T p.G456* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- ZNF148 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 203/287 reads (71%) | called by muse, mutect2, varscan2
- ZNF513 | c.375del p.P126Rfs*40 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | called by mutect2, pindel, varscan2
- ZNF595 | c.1413G>T p.K471N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AASS | c.1485A>G p.V495= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV62790882; called by muse, mutect2, varscan2
- ADCY7 | c.1011C>T p.P337= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs749723232, COSV54268835, COSV99576263; called by muse, mutect2, varscan2
- ADH4 | c.1083C>T p.I361= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV55501536; called by muse, mutect2, varscan2
- AJAP1 | c.1080C>T p.C360= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs1288652834, COSV65452214; called by muse, mutect2, varscan2
- ALLC | c.390C>T p.D130= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as rs201690293, COSV52996364; called by muse, mutect2, varscan2
- AOPEP | c.2409G>A p.K803= (on ENST00000375315 / NM_001193329.1; = p.K704= on NM_032823.5) | Silent (SNP) | VAF 35/67 reads (52%) | catalogued as COSV52994811; called by muse, mutect2, varscan2
- APBB3 | c.1407C>G p.V469= (on ENST00000357560 / NM_133173.2; = p.V476= on NM_006051.3) | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV60365896; called by muse, mutect2, varscan2
- APEX2 | c.297G>A p.L99= | Silent (SNP) | VAF 49/70 reads (70%) | catalogued as COSV66624276; called by muse, mutect2, varscan2
- APRT | c.174C>T p.I58= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1445678588, COSV51939031; called by muse, mutect2, varscan2
- ARMC1 | c.561C>T p.I187= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV52534267; called by muse, mutect2, varscan2
- ARSH | c.1068T>C p.G356= | Silent (SNP) | VAF 41/65 reads (63%) | catalogued as COSV66963516; called by muse, mutect2, varscan2
- ARSK | c.72G>A p.Q24= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV62455765; called by muse, mutect2, varscan2
- ATAD3A | c.273C>G p.S91= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV59234612; called by muse, mutect2, varscan2
- ATP2B2 | c.1071C>T p.G357= (on ENST00000352432; = p.G323= on NM_001683.5) | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as rs147871544; called by muse, mutect2, varscan2
- B3GALT1 | c.348C>T p.F116= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV59908745; called by muse, mutect2, varscan2
- BTBD17 | c.1377C>A p.A459= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV64730331; called by muse, mutect2, varscan2
- C2CD3 | c.850C>T p.L284= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1454694023, COSV58089437; called by muse, mutect2, varscan2
- CALCOCO1 | c.657G>A p.L219= | Silent (SNP) | VAF 156/460 reads (34%) | catalogued as COSV50417509; called by muse, mutect2, varscan2
- CDH22 | c.1941C>T p.L647= | Silent (SNP) | VAF 27/54 reads (50%) | catalogued as rs1337426291, COSV64838676, COSV64840201; called by muse, mutect2, varscan2
- CHD5 | c.3417G>A p.Q1139= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV52420286; called by muse, mutect2, varscan2
- CHD7 | c.1524T>C p.F508= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV71112850; called by muse, varscan2
- CHST7 | c.747C>T p.I249= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV52100557; called by muse, mutect2, varscan2
- CKAP2 | c.738A>G p.T246= (on ENST00000378037 / NM_001098525.2; = p.T245= on NM_018204.5) | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV51623453; called by muse, mutect2, varscan2
- CLSTN1 | c.174A>G p.P58= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs752067668, COSV63649686; called by mutect2, varscan2
- COL24A1 | c.417T>G p.P139= | Silent (SNP) | VAF 25/42 reads (60%) | catalogued as COSV65309894; called by muse, mutect2, varscan2
- CRNKL1 | c.2001C>T p.I667= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as rs1266513215, COSV66106367; called by muse, mutect2, varscan2
- CSMD3 | c.8502A>G p.G2834= (on ENST00000297405 / NM_001363185.1; = p.G2665= on NM_052900.3) | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV52249155; called by muse, mutect2, varscan2
- CUEDC1 | c.765C>T p.F255= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- CYP11A1 | c.306C>T p.I102= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs1238632066, COSV51433723; called by muse, mutect2, varscan2
- DEFB127 | c.171C>T p.I57= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs781609881, COSV101213825, COSV66688895; called by muse, mutect2, varscan2
- DENND5A | c.3762C>T p.I1254= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100065057, COSV60236125; called by muse, mutect2, varscan2
- DGKH | c.1683G>A p.L561= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV54936676; called by muse, mutect2, varscan2
- DMD | c.6801C>G p.L2267= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as COSV58895132; called by muse, mutect2, varscan2
- DNAH10 | c.4050G>A p.L1350= (on ENST00000409039; = p.L1289= on NM_207437.3) | Silent (SNP) | VAF 38/139 reads (27%) | catalogued as COSV68997507; called by muse, mutect2, varscan2
- DNAH10 | c.5118G>A p.L1706= (on ENST00000409039; = p.L1645= on NM_207437.3) | Silent (SNP) | VAF 35/88 reads (40%) | catalogued as COSV68997512; called by muse, mutect2, varscan2
- DNM3 | c.2343A>G p.T781= (on ENST00000355305 / NM_001350206.2; = p.T775= on NM_015569.5) | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs1042455697, COSV62462594; called by muse, mutect2, varscan2
- DOP1B | c.192C>T p.S64= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as COSV54280987; called by muse, mutect2, varscan2
- EIF2AK4 | c.477G>A p.Q159= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV55471304; called by muse, mutect2, varscan2
- EIF4G3 | c.2169T>C p.D723= | Silent (SNP) | VAF 35/180 reads (19%) | catalogued as COSV51688069; called by muse, mutect2, varscan2
- EPB41L2 | c.1287C>G p.L429= | Silent (SNP) | VAF 52/88 reads (59%) | catalogued as COSV61357357; called by muse, mutect2, varscan2
- EPHA6 | c.966T>C p.S322= | Silent (SNP) | VAF 64/215 reads (30%) | catalogued as COSV67583120; called by muse, mutect2, varscan2
- ETAA1 | c.1071G>A p.V357= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV55474460; called by muse, varscan2
- F12 | c.1095G>A p.K365= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1293772683, CM102469, COSV53692232; called by muse, mutect2, varscan2
- FAM53B | c.378C>T p.C126= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- FBXL6 | c.1072C>T p.L358= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as COSV57352654; called by muse, mutect2, varscan2
- FCRLB | c.726G>A p.A242= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as rs1348841341, COSV100396044; called by muse, mutect2, varscan2
- FECH | c.810C>T p.V270= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV50491724; called by muse, mutect2, varscan2
- FER1L6 | c.99A>C p.A33= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as COSV67551559; called by muse, mutect2, varscan2
- FGFR2 | c.1665A>G p.T555= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- FLAD1 | c.1281T>A p.V427= | Silent (SNP) | VAF 127/360 reads (35%) | catalogued as COSV52698370; called by muse, mutect2, varscan2
- FRAS1 | c.9621C>T p.P3207= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV53628811; called by muse, mutect2, varscan2
- FRAS1 | c.9771C>T p.V3257= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV53628825; called by muse, mutect2, varscan2
- FRMD4A | c.627C>T p.I209= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs754635018, COSV52729909; called by muse, mutect2, varscan2
- FXR1 | c.48C>T p.Y16= | Silent (SNP) | VAF 64/192 reads (33%) | catalogued as COSV59764570; called by muse, mutect2, varscan2
- GALM | c.747G>A p.K249= | Silent (SNP) | VAF 31/114 reads (27%) | catalogued as COSV55372854; called by muse, mutect2, varscan2
- GARNL3 | c.54G>A p.L18= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV59225374; called by muse, mutect2, varscan2
- GIGYF2 | c.555T>G p.G185= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV65251664; called by muse, mutect2, varscan2
- GLIS3 | c.2265C>T p.F755= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs1283204437, COSV60932589; called by muse, varscan2
- GNB4 | c.960A>G p.V320= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV51710644; called by muse, mutect2, varscan2
- GRIN2C | c.495C>T p.F165= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs759740884, COSV53115627; called by muse, mutect2, varscan2
- H1-7 | c.297G>A p.A99= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV58602604; called by muse, mutect2, varscan2
- HLA-DMB | c.6C>T p.I2= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- HMMR | c.237G>A p.K79= | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- HOXB8 | c.726G>A p.K242= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV53311092; called by muse, mutect2, varscan2
- HSP90B1 | c.1578G>A p.Q526= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as rs372371380; called by muse, mutect2, varscan2
- ID1 | c.24C>T p.T8= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs989359342, COSV101076862, COSV65888289; called by muse, mutect2, varscan2
- INO80D | c.555G>A p.E185= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV68958339; called by muse, mutect2, varscan2
- IQGAP1 | c.414T>C p.D138= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs767016252, COSV51588441; called by muse, mutect2, varscan2
- ITGAM | c.3246G>A p.L1082= (on ENST00000648685 / NM_001145808.2; = p.L1081= on NM_000632.4) | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs758314269, COSV54939734; called by muse, mutect2, varscan2
- JAKMIP1 | c.363C>T p.R121= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs573517329, COSV51530990; called by muse, mutect2, varscan2
- KATNAL2 | c.945C>T p.F315= (on ENST00000356157 / NM_001353899.1; = p.F243= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV55303524; called by muse, mutect2, varscan2
- KCNH6 | c.1719C>T p.P573= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs771445825, COSV59005622; called by muse, mutect2, varscan2
- KCNT2 | c.1347T>C p.C449= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs745377780, COSV54072713, COSV54093813; called by muse, mutect2, varscan2
- KERA | c.417A>G p.P139= | Silent (SNP) | VAF 25/114 reads (22%) | catalogued as rs375105205; called by muse, mutect2, varscan2
- KIRREL1 | c.1777C>A p.R593= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV63289462; called by muse, varscan2
- KLHL28 | c.762G>A p.L254= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV61888863; called by muse, mutect2, varscan2
- KLHL6 | c.1618C>T p.L540= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as COSV58066272; called by muse, mutect2, varscan2
- KRT3 | c.990T>C p.D330= | Silent (SNP) | VAF 80/258 reads (31%) | catalogued as COSV58816407; called by muse, mutect2, varscan2
- LAMB1 | c.3033C>T p.F1011= | Silent (SNP) | VAF 55/95 reads (58%) | catalogued as COSV55967608; called by muse, mutect2, varscan2
- LGR4 | c.2700C>T p.G900= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV58726506; called by muse, mutect2, varscan2
- LIG3 | c.1968G>A p.G656= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV52009348; called by muse, mutect2, varscan2
- LRATD2 | c.303G>A p.S101= | Silent (SNP) | VAF 5/51 reads (10%) | called by muse, mutect2
- LRIG2 | c.1065T>C p.F355= | Silent (SNP) | VAF 36/93 reads (39%) | catalogued as COSV63163104; called by muse, mutect2, varscan2
- LRRN4 | c.939C>G p.L313= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV66644297, COSV66646080; called by muse, mutect2, varscan2
- LRRTM4 | c.1164C>A p.T388= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV69139170, COSV69141054; called by muse, mutect2, varscan2
- MAGEE2 | c.957C>T p.V319= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as rs750976524, COSV64898128; called by muse, mutect2, varscan2
- MAGI1 | c.3516G>A p.E1172= (on ENST00000402939 / NM_001033057.2; = p.E1201= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs1323946721, COSV58328126; called by muse, mutect2, varscan2
- MAP4K3 | c.90C>T p.V30= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV55715714; called by muse, mutect2, varscan2
- MAPKAPK3 | c.1131G>A p.Q377= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV63597972; called by muse, mutect2, varscan2
- MEIS1 | c.66G>A p.T22= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV55483876, COSV55491346; called by muse, mutect2, varscan2
- MID1 | c.438G>A p.L146= | Silent (SNP) | VAF 38/63 reads (60%) | catalogued as rs779090894, COSV58197002; called by muse, mutect2, varscan2
- MIPOL1 | c.450C>T p.L150= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV59388578; called by muse, mutect2, varscan2
- MRPL39 | c.141C>G p.L47= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as COSV56261535; called by muse, mutect2, varscan2
- MS4A14 | c.1707G>A p.Q569= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV55736527; called by muse, mutect2, varscan2
- MYCBP2 | c.528A>G p.T176= (on ENST00000357337; = p.T214= on NM_015057.5) | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV62029633; called by muse, mutect2, varscan2
- MYCN | c.105C>T p.F35= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV55259932; called by muse, mutect2, varscan2
- MYOM3 | c.4266C>T p.I1422= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs768823648, COSV58397249; called by muse, mutect2, varscan2
- NAA15 | c.2070G>A p.L690= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV56721168; called by muse, mutect2, varscan2
- NAPB | c.315T>C p.N105= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV65464860; called by muse, mutect2, varscan2
- NCEH1 | c.399C>G p.P133= (on ENST00000538775; = p.P101= on NM_020792.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs373507616, COSV56436223; called by muse, mutect2, varscan2
- NEXMIF | c.1266G>A p.K422= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV50058489; called by muse, mutect2, varscan2
- NLRC5 | c.2151G>A p.Q717= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV52659266; called by muse, mutect2, varscan2
- NLRP2 | c.693A>G p.A231= | Silent (SNP) | VAF 32/49 reads (65%) | catalogued as rs1228967269, COSV54757719; called by muse, mutect2, varscan2
- NMUR2 | c.288C>A p.L96= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV54921079; called by muse, mutect2, varscan2
- NPAP1 | c.1833G>A p.Q611= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV61509056; called by muse, mutect2, varscan2
- NPBWR1 | c.636C>T p.F212= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV58695530; called by muse, mutect2, varscan2
- NR5A2 | c.381C>T p.N127= (on ENST00000367362 / NM_205860.3; = p.N81= on NM_003822.5) | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV52654010; called by muse, mutect2, varscan2
- NRXN1 | c.990T>C p.Y330= | Silent (SNP) | VAF 70/185 reads (38%) | catalogued as COSV58473134; called by muse, mutect2, varscan2
- NSMCE3 | c.261G>A p.L87= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as COSV54279591; called by muse, mutect2, varscan2
- OGDH | c.2451C>T p.F817= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as rs368953616; called by muse, mutect2, varscan2
- OR6C1 | c.337C>T p.L113= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs149008799; called by muse, mutect2, varscan2
- OR6C2 | c.111A>G p.V37= | Silent (SNP) | VAF 21/65 reads (32%) | catalogued as rs142313431; called by muse, mutect2, varscan2
- OTOF | c.1698G>C p.R566= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV55510521; called by muse, mutect2, varscan2
- P2RX6 | c.1062C>T p.F354= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV60383821, COSV60385079; called by muse, varscan2
- PANX2 | c.178C>T p.L60= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV50303070; called by muse, mutect2
- PAX4 | c.873G>A p.L291= | Silent (SNP) | VAF 20/131 reads (15%) | catalogued as COSV58390031; called by muse, mutect2, varscan2
- PCBP1 | c.915C>T p.I305= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs769538150, COSV57850000; called by muse, mutect2, varscan2
- PCDH1 | c.1095C>T p.N365= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as COSV54616917; called by muse, mutect2, varscan2
- PCDH7 | c.1227C>T p.N409= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs372895036; called by muse, mutect2, varscan2
- PCSK9 | c.1245G>A p.L415= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV56163416; called by muse, mutect2, varscan2
- PCYOX1L | c.321G>C p.V107= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs750379727, COSV51003852; called by muse, mutect2, varscan2
- PDE3A | c.825G>A p.L275= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs750288734, COSV62967221; called by muse, mutect2, varscan2
- PEAK3 | c.873C>T p.A291= | Silent (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- PHACTR1 | c.732A>G p.K244= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV60674150; called by muse, mutect2, varscan2
- PHB | c.273A>G p.T91= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV55931437; called by muse, mutect2, varscan2
- PHF20 | c.1110G>A p.L370= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as COSV59187443; called by muse, mutect2, varscan2
- PLA2G6 | c.246G>A p.V82= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as rs1328823380, COSV59271941; called by muse, mutect2, varscan2
- PLCB3 | c.591C>T p.F197= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV54190540; called by muse, mutect2, varscan2
- PLK3 | c.768G>A p.G256= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV59500463; called by muse, mutect2, varscan2
- PLXNA1 | c.1968C>T p.F656= | Silent (SNP) | VAF 23/214 reads (11%) | catalogued as rs751981690, COSV52529869; called by muse, mutect2, varscan2
- PLXNA2 | c.1032G>A p.K344= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV65442810; called by muse, mutect2, varscan2
- POFUT2 | c.1218G>A p.T406= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs756097099, COSV57960199; called by muse, mutect2, varscan2
- PPFIA2 | c.132T>C p.R44= | Silent (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- PPM1H | c.429C>T p.S143= | Silent (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- PPP1R15B | c.648C>T p.F216= | Silent (SNP) | VAF 44/149 reads (30%) | catalogued as COSV65816171; called by muse, mutect2, varscan2
- PREX2 | c.4581C>T p.I1527= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as rs747726231, COSV55786322; called by muse, mutect2, varscan2
- PRKD1 | c.2738G>A p.*913= | Silent (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- PRMT9 | c.90G>A p.Q30= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV59360520; called by muse, mutect2, varscan2
- RAB18 | c.42C>T p.I14= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.2689C>T p.L897= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV51485252; called by muse, mutect2, varscan2
- RAD9A | c.420G>A p.S140= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs761923660, COSV57237533; called by muse, mutect2, varscan2
- RAP2A | c.84C>T p.F28= | Silent (SNP) | VAF 35/151 reads (23%) | catalogued as COSV55355545; called by muse, mutect2, varscan2
- RAP2B | c.456G>A p.S152= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV60257274; called by mutect2, varscan2
- RBMXL1 | c.117G>A p.L39= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV53103574; called by muse, mutect2, varscan2
- RGS22 | c.436T>C p.L146= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV62664818; called by muse, mutect2, varscan2
- ROS1 | c.6294G>T p.V2098= | Silent (SNP) | VAF 53/97 reads (55%) | catalogued as COSV63858535, COSV63862810; called by muse, mutect2, varscan2
- RPL26L1 | c.87C>T p.I29= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as COSV54200009; called by muse, mutect2, varscan2
- SALL4 | c.3105C>G p.G1035= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as rs555887614, COSV53854363; called by muse, mutect2, varscan2
- SDR16C5 | c.132C>T p.L44= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV58127479; called by muse, mutect2, varscan2
- SERPINE2 | c.792G>A p.P264= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs1288897051, COSV51456402, COSV51458928; called by muse, mutect2, varscan2
- SHKBP1 | c.1743C>T p.A581= | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as COSV52541828; called by muse, mutect2, varscan2
- SIPA1L2 | c.4692G>A p.L1564= | Silent (SNP) | VAF 47/155 reads (30%) | catalogued as COSV53394869; called by muse, mutect2, varscan2
- SLC16A13 | c.567C>T p.L189= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV57274664; called by muse, mutect2, varscan2
- SLC25A24 | c.147G>A p.R49= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV51449159; called by muse, mutect2, varscan2
- SLC38A10 | c.2511G>A p.Q837= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV55847332; called by muse, mutect2, varscan2
- SLC38A9 | c.1572C>T p.L524= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs1438331072, COSV59424955; called by muse, mutect2, varscan2
- SLC7A13 | c.516C>T p.S172= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV52535875; called by muse, mutect2, varscan2
- SLC8A3 | c.945G>A p.E315= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV63523982; called by muse, mutect2, varscan2
- SNX19 | c.2502A>G p.E834= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV56287270; called by muse, mutect2, varscan2
- SOWAHC | c.1269C>T p.L423= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV61781116; called by muse, mutect2, varscan2
- SPEN | c.10994G>A p.*3665= | Silent (SNP) | VAF 78/214 reads (36%) | called by muse, varscan2
- SPOPL | c.306C>T p.F102= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV54514830; called by muse, mutect2, varscan2
- STPG4 | c.327G>A p.K109= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV54279366; called by muse, mutect2, varscan2
- SULF2 | c.2007C>G p.T669= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV63418282; called by muse, mutect2, varscan2
- SULT1A2 | c.723C>T p.T241= | Silent (SNP) | VAF 28/163 reads (17%) | catalogued as COSV57682487; called by muse, mutect2, varscan2
- SUOX | c.30C>T p.L10= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV57189371; called by muse, mutect2, varscan2
- SUPV3L1 | c.207G>A p.V69= | Silent (SNP) | VAF 24/134 reads (18%) | catalogued as COSV62845868; called by muse, mutect2, varscan2
- SYNJ1 | c.4206A>G p.Q1402= | Silent (SNP) | VAF 33/68 reads (49%) | catalogued as COSV59152243; called by muse, mutect2, varscan2
- TACC2 | c.3096G>A p.K1032= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV57764131; called by muse, mutect2, varscan2
- TALDO1 | c.510C>T p.F170= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV59798051; called by muse, mutect2, varscan2
- TBCD | c.3532C>T p.L1178= | Silent (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- TDRD10 | c.252A>G p.T84= | Silent (SNP) | VAF 49/185 reads (26%) | catalogued as COSV63812325, COSV63813169; called by muse, mutect2, varscan2
- TIGD2 | c.711C>T p.F237= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV57648362; called by muse, mutect2, varscan2
- TIMM44 | c.1323G>A p.L441= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV54493162; called by muse, mutect2, varscan2
- TIMP4 | c.460C>T p.L154= | Silent (SNP) | VAF 81/267 reads (30%) | catalogued as COSV55139320; called by muse, mutect2, varscan2
- TMC3 | c.1539C>T p.I513= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs934337804, COSV63923832; called by muse, mutect2, varscan2
- TMC8 | c.1509C>T p.L503= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV59210578; called by muse, mutect2, varscan2
- TMEM220 | c.183T>C p.S61= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV59379708; called by muse, mutect2, varscan2
- TMEM80 | c.327C>T p.T109= (on ENST00000526170 / NM_001276274.1; = p.T171= on NM_174940.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs766520397, COSV59347888; called by muse, varscan2
- TMPRSS7 | c.1608C>T p.L536= (on ENST00000452346; = p.L410= on NM_001042575.2) | Silent (SNP) | VAF 39/305 reads (13%) | catalogued as COSV69980233, COSV69981698; called by muse, mutect2, varscan2
- TNMD | c.816C>T p.G272= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV65977483; called by muse, mutect2, varscan2
- TONSL | c.3288C>T p.T1096= | Silent (SNP) | VAF 35/57 reads (61%) | catalogued as COSV68048870; called by muse, mutect2, varscan2
- TOP3B | c.813G>A p.Q271= | Silent (SNP) | VAF 35/115 reads (30%) | catalogued as COSV64118537; called by muse, mutect2, varscan2
- TP53BP2 | c.1671G>A p.P557= (on ENST00000343537 / NM_001031685.3; = p.P428= on NM_005426.2) | Silent (SNP) | VAF 53/177 reads (30%) | catalogued as rs765016756, COSV100636732, COSV59070836; called by muse, mutect2, varscan2
- TPRN | c.1534C>T p.L512= | Silent (SNP) | VAF 52/92 reads (57%) | catalogued as COSV58808355; called by muse, mutect2, varscan2
- TRIL | c.1095C>T p.C365= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- TRIM41 | c.1237C>T p.L413= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs1377240526, COSV59320605; called by muse, mutect2, varscan2
- TRIP11 | c.4593A>T p.A1531= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV50939961; called by muse, mutect2, varscan2
- TRPA1 | c.504T>A p.A168= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as COSV51567967; called by muse, mutect2, varscan2
- TSTD2 | c.174C>A p.A58= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV57846911; called by muse, mutect2, varscan2
- TTF2 | c.2151C>G p.L717= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV65632161, COSV65633164; called by muse, mutect2, varscan2
- TTN | c.82362T>C p.I27454= (on ENST00000591111; = p.I20030= on NM_003319.4) | Silent (SNP) | VAF 39/133 reads (29%) | catalogued as COSV60199609; called by muse, mutect2, varscan2
- UGT2B7 | c.516C>T p.L172= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV59444462; called by muse, mutect2, varscan2
- UNK | c.1167C>T p.S389= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV53144589; called by muse, mutect2, varscan2
- USH2A | c.607C>T p.L203= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV56401710; called by muse, mutect2, varscan2
- USP10 | c.267A>G p.E89= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs774453217, COSV54750969; called by muse, mutect2, varscan2
- WDR77 | c.450G>A p.K150= | Silent (SNP) | VAF 43/87 reads (49%) | catalogued as COSV52385770, COSV52385858; called by muse, mutect2, varscan2
- WDR91 | c.219C>T p.F73= | Silent (SNP) | VAF 49/139 reads (35%) | catalogued as COSV60371082; called by muse, mutect2, varscan2
- WNT9B | c.1068G>A p.K356= | Silent (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2
- ZCCHC12 | c.1119G>A p.L373= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV59571050, COSV59572405; called by muse, mutect2, varscan2
- ZDHHC5 | c.2136G>A p.E712= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs1160943646, COSV54708186; called by muse, mutect2, varscan2
- ZNF337 | c.435G>A p.R145= | Silent (SNP) | VAF 36/200 reads (18%) | catalogued as COSV53322344; called by muse, mutect2, varscan2
- CCDC18 | c.-3+388C>T | Intron (SNP) | VAF 13/71 reads (18%) | catalogued as rs781258552, COSV58145603; called by muse, mutect2, varscan2
- CYP2R1 | c.-2C>G | 5'UTR (SNP) | VAF 4/21 reads (19%) | catalogued as rs200462787, COSV58127056; called by muse, varscan2
- EIF4G1 | c.-40G>C | 5'UTR (SNP) | VAF 17/60 reads (28%) | catalogued as COSV100071765; called by muse, mutect2, varscan2
- GRK5 | c.148+7155_148+7156delinsT | Intron (DEL) | VAF 15/50 reads (30%) | called by pindel, varscan2*
- HERC2P3 | n.1673C>A | RNA (SNP) | VAF 6/32 reads (19%) | called by mutect2, varscan2
- KIR3DX1 | n.167C>T | RNA (SNP) | VAF 40/58 reads (69%) | catalogued as rs372931579; called by muse, mutect2, varscan2
- LAMTOR5 | chr1:110407775 G>A | 5'Flank (SNP) | VAF 11/39 reads (28%) | catalogued as COSV56679251; called by muse, mutect2, varscan2
- LINC01588 | n.67A>G | RNA (SNP) | VAF 12/42 reads (29%) | called by muse, varscan2
- MACF1 | c.15832-11296C>T | Intron (SNP) | VAF 7/19 reads (37%) | catalogued as rs754059931, COSV57132604; called by muse, mutect2, varscan2
- MIR802 | n.60G>T | RNA (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2, varscan2
- NDUFA13 | chr19:19516030 G>C | 5'Flank (SNP) | VAF 19/39 reads (49%) | catalogued as COSV53064483; called by muse, mutect2, varscan2
- OPRPN | c.-2G>A | 5'UTR (SNP) | VAF 9/43 reads (21%) | catalogued as COSV101271087; called by muse, mutect2, varscan2
- PARGP1 | n.531G>C | RNA (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- PAX6 | c.142-122A>T | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as COSV53794707; called by muse, mutect2, varscan2
- RPL17 | c.-151G>A | 5'UTR (SNP) | VAF 14/43 reads (33%) | catalogued as rs1188210347, COSV100271623; called by muse, mutect2, varscan2
- RPL24 | c.-2C>A | 5'UTR (SNP) | VAF 17/70 reads (24%) | catalogued as COSV101231177; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 4/34 reads (12%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by mutect2, varscan2
- TMEM143 | c.-2C>T | 5'UTR (SNP) | VAF 116/169 reads (69%) | catalogued as COSV53157824; called by muse, varscan2
- TSPAN14 | chr10:80520835 A>G | 3'Flank (SNP) | VAF 18/116 reads (16%) | catalogued as COSV55420293; called by muse, mutect2, varscan2
- ZNRF2 | c.469+3996G>A | Intron (SNP) | VAF 35/117 reads (30%) | catalogued as COSV100546176, COSV59910545; called by muse, mutect2, varscan2
